Somatic mutation profile of tumor specimen RC-B5D5-TBP1-A (aliquot RC-B5D5-TBP1-A-1-0-D-A93N-47) from RC case RC-B5D5, project RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL). Sex at birth: male; Vital status: Alive; Primary diagnosis: Peripheral T-cell lymphoma, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 19.5 years (7,130 days).
Specimen RC-B5D5-TBP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 949d239b-48d9-40e3-b782-1b1d23d8d045.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen RC-B5D5-NB1-A (Granulocytes; tissue type Normal), aliquot RC-B5D5-NB1-A-1-0-D-A93N-47; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/de0407c1-181a-4199-a796-fe3fc27bbde5

The open-access MAF lists 1 somatic variant for this specimen: 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC107023.1 | n.26-6147C>A | Intron (SNP) | VAF 9/120 reads (8%) | called by muse, mutect2
